HCMI case HCM-BROD-0451-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9bfc8171-9b0a-4636-a230-a0a34ebaaac2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1947; Vital status: Dead; Days to death: 278 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.9; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Lower third of esophagus; Classification of tumor: primary; Age at diagnosis: 71.0 years (25,951 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IV; AJCC pathologic T: T3; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Prior malignancy: no; Prior treatment: Yes; Esophageal columnar metaplasia present: No; Gastric esophageal junction involvement: No; Goblet cells columnar mucosa present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Fluorouracil + Leucovorin + Oxaliplatin + Paclitaxel; Treatment intent type: Neoadjuvant; Days to treatment start: 26 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Neoadjuvant; Days to treatment start: 26 days.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 278 days; Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 274.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 87 kg; Height: 172 cm; BMI: 29.
- Timepoint category: Prior to Diagnosis; Risk factors: GERD.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Alcohol intensity: Non-Drinker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-BROD-0451-C15-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0451-C15-85C: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 2.
